Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9L6, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9L6-01A (Primary Tumor).

[page 1 of 3]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

ICD-6.3
Adenocarcinoma NOS 8144/3
Site: Prostate NOS C61.9
9/1/2014

Gross description:

1. (Prostate gland): Prostate gland: Weight: 30 g, Volume: 25 ml, Size: 3.5 x 3.7 x 4 cm. Adherent seminal vesicles and deferent duct: right side: 3.5 cm, left side: 3 cm. The surface is marked with green ink on the right side, blue ink on the left side. Total of the cross sections: 1.7 cm.
2. (Lymph nodes, right side): 7.5 x 6 cm measuring adipose tissue containing 14 nodes measuring up to 1.5 cm.
3. (Lymph nodes, left side): 4 x 4.5 cm measuring adipose tissue containing 3 nodes measuring up 1.5 x 0.5 cm.

Microscopy:

1. Apex right and left: Right 5 tissue blocks, left 7 tissue blocks (total 12 tissue blocks). 2 cross sections: Right 10 tissue blocks, left 10 tissue blocks (total 20 tissue blocks). Basis right and left: Right 8 tissue blocks, left 8 tissue blocks (total 16 tissue blocks). Seminal vesicles right and left: Right 4 tissue blocks, left 2 tissue blocks (total 6 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).
2. Frozen lymph nodes right: 15 tissue blocks.
3. Frozen lymph nodes left: 9 tissue blocks.

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5: 70%, Gleason 4: 25%, Gleason 3: 5%). Tumor involves both lobes with the main focus on the right side. Maximum tumor diameter: 34 mm. Perineural invasion. Tumor infiltration into peri-prostatic adipose tissue in 5 tissue blocks with the main focus around the seminal vesicles (maximum invasion length 3 mm, maximal invasion depth 2 mm). Positive surgical margin in 3 blocks (contact length 3 mm; Gleason 4 and 5).

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor infiltration into both seminal vesicles. Tumor-free deferent ducts.

2. (Lymph nodes, right side): Thirteen tumor-free lymph nodes (0/13).
3. (Lymph nodes, left side): Twelve tumor-free lymph nodes (0/12).

[page 2 of 3]
Tumor classification

(in consideration of the parallel report and immunohistochemical analyses):

pT3b, Gleason 5+4=9 (Gleason 5: 70%, Gleason 4: 25%, Gleason 3: 5%), maximum tumor diameter: 34 mm, tumor volume approx. 17.19 ml (Gleason 5: 12.03 ml, Gleason 4: 4.29 ml, Gleason 3: 0.87 ml), pN0 (0/25), R1

Comments:

Tumor infiltration into peri-prostatic adipose tissue in 5 tissue blocks, mainly around the seminal vesicles (tissue blocks SBR1, SBR2, SBR3, SBL1, SBL2, (maximum invasion length 3 mm, maximal invasion depth 2 mm). Positive surgical margin in 3 tissue blocks (AR1A, AR1B, SBR1, (contact length 3 mm; Gleason 4 and 5).

Additional immunohistochemical analyses (AE1/AE3) of lymph nodes (tissue blocks 2F, 2G, 2D) did not reveal any metastases.

One macroscopic image for tumor mapping.

*See dx discrepancy form for
Gleason 5+5.*

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason 5+4	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Gleason 5+5	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Frozen sample tissue block submitted to TCGA has a different Gleason score than the frozen tissue block that was used for diagnosis.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 25e0896f-7b9a-40bb-93c2-08f2d9af279c (TCGA-ZG-A9L6.1EAD6485-88D7-467C-8E00-335B3D7056B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).